Somatic mutation profile of tumor specimen ALCH-B2YJ-TTP1-A (aliquot ALCH-B2YJ-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B2YJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.0 years (29,571 days).
Specimen ALCH-B2YJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a2ea505-38dc-474c-b426-bd052bbb413a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2YJ-NB1-A (Blood Derived Normal), aliquot ALCH-B2YJ-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff0602e2-59b3-40d3-9d61-e686a2368331

The open-access MAF lists 221 somatic variants for this specimen: 150 protein-altering or splice-affecting, 50 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 50, Intron 12, Nonsense Mutation 10, RNA 5, Splice Site 4, 3'UTR 3, Frame Shift Del 3, Frame Shift Ins 2, 5'UTR 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 315/718 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABHD12B | c.169A>G p.S57G | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs983979280; called by muse, mutect2, varscan2
- AC011005.1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 35/296 reads (12%) | catalogued as rs767103897; called by muse, mutect2, varscan2
- AGMO | c.728G>T p.W243L | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100693655; called by muse, mutect2, varscan2
- ASTN1 | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs751815220, COSV56064909; called by muse, mutect2, varscan2
- ATP10B | c.2806G>A p.D936N | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs757387528, COSV59155951; called by muse, mutect2, varscan2
- BCAS3 | c.1699C>T p.P567S (on ENST00000390652 / NM_001353144.2; = p.P552S on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/359 reads (11%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.995); catalogued as rs779715583; called by muse, mutect2, varscan2
- BRINP3 | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 44/328 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.066); catalogued as COSV100819035; called by muse, mutect2, varscan2
- BTBD7 | c.1019C>G p.S340C | Missense Mutation (SNP) | VAF 146/488 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as rs1473586051, COSV54137920; called by muse, mutect2, varscan2
- CACNA1I | c.4345C>T p.R1449C | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1383407823, COSV60810710, COSV60813881; called by muse, mutect2, varscan2
- CEP128 | c.2024G>T p.R675M | Missense Mutation (SNP) | VAF 75/253 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.326); catalogued as COSV99823902; called by muse, mutect2, varscan2
- CHTF18 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50100228, COSV99135559; called by muse, mutect2, varscan2
- CMTR2 | c.467A>T p.H156L | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57603683; called by muse, mutect2, varscan2
- CNTNAP2 | c.882G>T p.R294S | Missense Mutation (SNP) | VAF 58/327 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as COSV100663087, COSV100669189; called by muse, mutect2, varscan2
- CRHR1 | c.539G>A p.R180Q (on ENST00000398285 / NM_001145146.2; = p.R151Q on NM_004382.5) | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs951637702, COSV53281011; called by muse, mutect2, varscan2
- DAGLB | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 43/389 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV51702456; called by muse, mutect2, varscan2
- DENND2B | c.1175G>T p.R392L | Missense Mutation (SNP) | VAF 56/282 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58201975; called by muse, mutect2, varscan2
- DGCR2 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 154/325 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.068); catalogued as rs1341312055, COSV54217469; called by muse, mutect2, varscan2
- DGKK | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 34/508 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.146); catalogued as COSV101053179; called by muse, mutect2
- ERBB2 | c.274A>T p.R92W | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV54062176; called by muse, mutect2, varscan2
- FAM171B | c.1576C>A p.H526N | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.131); catalogued as COSV100488982, COSV99079820; called by muse, mutect2, varscan2
- FAM205A | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as rs550998564; called by muse, varscan2
- FBXO39 | c.752T>A p.L251H | Missense Mutation (SNP) | VAF 56/460 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1434279104; called by muse, mutect2, varscan2
- FGD5 | c.2722G>A p.V908M | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs201010968; called by muse, mutect2, varscan2
- FHIT | c.430G>T p.V144F | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1217980455; called by muse, mutect2, varscan2
- GBA3 | c.1049C>A p.P350Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101545558; called by muse, mutect2, varscan2
- GNLY | c.187G>C p.G63R | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs1255741552; called by muse, mutect2, varscan2
- H2BW2 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.788); catalogued as COSV54583748; called by muse, mutect2, varscan2
- HAPLN1 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 83/553 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs779648824, COSV57146725; called by muse, mutect2, varscan2
- HRH3 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as COSV58048647; called by muse, mutect2
- IGF2BP3 | c.1214C>G p.T405R | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV51679900; called by muse, mutect2, varscan2
- IGFBP4 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 92/243 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs1203274697; called by muse, mutect2, varscan2
- IQGAP2 | c.62A>G p.E21G | Missense Mutation (SNP) | VAF 65/308 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs777521275; called by muse, mutect2, varscan2
- KCNG2 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs746404020; called by muse, mutect2, varscan2
- LRG1 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.132); catalogued as rs115346350, COSV56703972; called by muse, varscan2
- NLRP3 | c.2359G>A p.D787N | Missense Mutation (SNP) | VAF 42/796 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs201814076, COSV100275005; called by muse, mutect2
- NOS3 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as rs145805216; called by muse, mutect2, varscan2
- OR5AK2 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 52/383 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs372725475, COSV58805334; called by muse, mutect2, varscan2
- OVCH2 | c.1011C>A p.S337R | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as rs374428307; called by muse, mutect2, varscan2
- PCDH17 | c.2056G>T p.G686* | Nonsense Mutation (SNP) | VAF 29/216 reads (13%) | catalogued as rs1320017052, COSV64972702; called by muse, mutect2, varscan2
- PCDHB3 | c.1854G>T p.W618C | Missense Mutation (SNP) | VAF 81/546 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1374862386; called by muse, mutect2, varscan2
- PDE3A | c.1535G>T p.R512L | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as rs185449585, COSV62982228; called by muse, mutect2
- PHF20 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 29/230 reads (13%) | catalogued as rs989066814; called by muse, mutect2, varscan2
- PRAMEF20 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 36/726 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.082); catalogued as rs1298412469; called by muse, mutect2
- RBMXL3 | c.2783G>T p.R928L | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV57751604; called by muse, mutect2, varscan2
- RNF144A | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 115/419 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.123); catalogued as rs201973870; called by muse, mutect2, varscan2
- SI | c.3541C>A p.P1181T | Missense Mutation (SNP) | VAF 74/492 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52294082; called by muse, mutect2, varscan2
- SLC6A3 | c.342C>G p.F114L | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV54369506; called by muse, mutect2
- SPIC | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.054); catalogued as rs201311054; called by muse, mutect2, varscan2
- SPTAN1 | c.5965G>A p.E1989K | Missense Mutation (SNP) | VAF 56/284 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100823962; called by muse, mutect2, varscan2
- SYNPO | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs754284257; called by muse, mutect2, varscan2
- TAB2 | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 66/481 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762446750; called by muse, mutect2, varscan2
- TRIM58 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV63569176; called by muse, mutect2, varscan2
- TSHZ3 | c.1892C>A p.P631Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.692); catalogued as COSV99553333; called by muse, mutect2, varscan2
- TXLNA | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776440607; called by muse, varscan2
- UBR5 | c.6070C>T p.R2024* | Nonsense Mutation (SNP) | VAF 283/653 reads (43%) | catalogued as COSV55292770; called by muse, mutect2, varscan2
- UCMA | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 92/327 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66321313, COSV66321927; called by muse, mutect2, varscan2
- VRTN | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs769359623, COSV56442884; called by muse, mutect2, varscan2
- WWC3 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs921188048; called by muse, mutect2
- ZC3H12B | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1216986299; called by muse, mutect2, varscan2
- ZNF394 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768156574; called by muse, mutect2, varscan2
- ZNF649 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 26/121 reads (21%) | catalogued as COSV56814866; called by muse, mutect2, varscan2
- AARS2 | c.2054A>C p.Q685P | Missense Mutation (SNP) | VAF 43/428 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ACOT4 | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ADAMTS14 | c.959_961del p.L320_S321delinsR | In Frame Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel
- ADAMTS8 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.179); called by muse, mutect2
- ADAMTS9 | c.5591A>G p.Y1864C | Missense Mutation (SNP) | VAF 106/399 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.8414T>G p.L2805R | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AFF2 | c.597C>G p.Y199* | Nonsense Mutation (SNP) | VAF 24/372 reads (6%) | called by muse, mutect2
- AGMO | c.729G>T p.W243C | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGO3 | c.1260G>T p.Q420H | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- APAF1 | c.1940G>T p.G647V (on ENST00000551964 / NM_181861.2; = p.G636V on NM_001160.3) | Missense Mutation (SNP) | VAF 100/347 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- APLP1 | c.1357C>G p.L453V | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARAF | c.96G>T p.V32= | Splice Region (SNP) | VAF 9/119 reads (8%) | called by muse, mutect2
- ARFGAP1 | c.325_326insT p.A109Vfs*4 | Frame Shift Ins (INS) | VAF 10/37 reads (27%) | called by mutect2, pindel
- ATM | c.4905del p.Q1636Rfs*10 | Frame Shift Del (DEL) | VAF 77/503 reads (15%) | called by mutect2, pindel, varscan2
- ATXN3L | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 18/333 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.481); called by muse, mutect2
- BNIP5 | c.1850A>T p.H617L | Missense Mutation (SNP) | VAF 38/336 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- CADPS2 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CCDC180 | c.2671G>T p.A891S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CCDC180 | c.3903-1G>T p.X1301_splice | Splice Site (SNP) | VAF 22/143 reads (15%) | called by muse, mutect2, varscan2
- CNGB3 | c.216A>C p.K72N | Missense Mutation (SNP) | VAF 79/911 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- COL2A1 | c.1137del p.T380Lfs*249 | Frame Shift Del (DEL) | VAF 71/269 reads (26%) | called by mutect2, pindel, varscan2
- CPS1 | c.3704C>A p.A1235D | Missense Mutation (SNP) | VAF 77/526 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CTNNA3 | c.2266-2A>G p.X756_splice | Splice Site (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2
- CUL9 | c.2671C>T p.Q891* | Nonsense Mutation (SNP) | VAF 88/661 reads (13%) | called by muse, mutect2, varscan2
- DCDC1 | c.2958G>T p.K986N (on ENST00000597505 / NM_001367979.1; = p.K93N on NM_020869.3) | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.323); called by muse, mutect2
- DCTN3 | c.242C>G p.A81G | Missense Mutation (SNP) | VAF 106/336 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- DKK2 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- DLK2 | c.647G>A p.C216Y | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLL3 | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); called by muse, mutect2
- DOCK4 | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 106/442 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EPC2 | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- EPC2 | c.1519T>A p.C507S | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.346); called by muse, mutect2
- FGF10 | c.255C>A p.F85L | Missense Mutation (SNP) | VAF 77/717 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GLI2 | c.4088C>T p.T1363I (on ENST00000361492 / NM_001374353.1; = p.T1380I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GPR158 | c.1670C>G p.S557* | Nonsense Mutation (SNP) | VAF 79/656 reads (12%) | called by muse, mutect2, varscan2
- GPT | c.1411C>G p.L471V | Missense Mutation (SNP) | VAF 402/1044 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- IGHA1 | c.901G>C p.A301P | Missense Mutation (SNP) | VAF 64/623 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITIH2 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 27/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIAA1549L | c.3101C>T p.T1034I (on ENST00000321505; = p.T1331I on NM_012194.3) | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP1B | c.355A>T p.N119Y | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- LRRD1 | c.1571T>A p.I524K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.139); called by muse, mutect2
- LY9 | c.1001C>G p.P334R | Missense Mutation (SNP) | VAF 83/363 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAGEA8 | c.519C>A p.D173E | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- MCM3AP | c.1346G>C p.R449T | Missense Mutation (SNP) | VAF 112/579 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- MEGF6 | c.2022G>T p.K674N | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- MEGF6 | c.2020A>C p.K674Q | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); called by muse, mutect2
- MLXIP | c.2038G>T p.D680Y | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NAP1L2 | c.321del p.V108Lfs*6 | Frame Shift Del (DEL) | VAF 31/259 reads (12%) | called by mutect2, pindel, varscan2
- NLRP4 | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10S1 | c.342G>T p.Q114H | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR13G1 | c.584T>C p.M195T | Missense Mutation (SNP) | VAF 85/421 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- OR4M1 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 152/2185 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- OR4Q3 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 59/1457 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.089); called by muse, mutect2
- OR51A7 | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51A7 | c.627C>A p.D209E | Missense Mutation (SNP) | VAF 84/600 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PAK1 | c.1391A>G p.Y464C | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PATJ | c.4466A>G p.N1489S | Missense Mutation (SNP) | VAF 14/392 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.194); called by muse, mutect2
- PCDH17 | c.722C>G p.P241R | Missense Mutation (SNP) | VAF 48/269 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH17 | c.2057G>T p.G686V | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PCDHB6 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 46/322 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- PCDHGB1 | c.1261A>G p.T421A | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- PCNX2 | c.5999C>T p.P2000L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PGC | c.335A>T p.H112L | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PLCL2 | c.1222T>C p.Y408H (on ENST00000615277 / NM_001144382.2; = p.Y282H on NM_015184.5) | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHA6 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- POTEF | c.2155G>C p.A719P | Missense Mutation (SNP) | VAF 70/712 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PRPH2 | c.828G>C p.E276D | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2
- RAB6C | c.368T>A p.L123Q | Missense Mutation (SNP) | VAF 25/554 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RELN | c.50dup p.A19Gfs*67 | Frame Shift Ins (INS) | VAF 12/106 reads (11%) | called by mutect2, varscan2
- RING1 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SERPINA9 | c.598A>G p.M200V | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.398); called by muse, varscan2
- SFXN3 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SGCZ | c.632C>A p.P211H | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SH3KBP1 | c.1061C>G p.T354S | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SLC13A3 | c.833G>T p.W278L | Missense Mutation (SNP) | VAF 37/270 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC29A2 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 64/450 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SLC4A10 | c.1752-1G>T p.X584_splice (on ENST00000446997 / NM_001354461.2; = p.X554_splice on NM_022058.4 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.85-1G>A p.X29_splice | Splice Site (SNP) | VAF 90/559 reads (16%) | called by muse, mutect2, varscan2
- SMAP1 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOWAHB | c.1991A>G p.N664S | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SVIL | c.4907G>C p.C1636S (on ENST00000355867 / NM_021738.3; = p.C1210S on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- TNN | c.1784A>G p.E595G | Missense Mutation (SNP) | VAF 60/602 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- TRIM62 | c.798T>A p.Y266* | Nonsense Mutation (SNP) | VAF 13/302 reads (4%) | called by muse, mutect2
- TSHZ3 | c.1891C>A p.P631T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UBA2 | c.230A>G p.K77R | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- XYLB | c.1511C>T p.T504I | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ZFYVE9 | c.2533A>C p.K845Q | Missense Mutation (SNP) | VAF 75/299 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ZSWIM1 | c.1086G>C p.K362N | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.022); called by muse, mutect2
- ACBD5 | c.822G>C p.G274= (on ENST00000375888 / NM_001352568.1; = p.G265= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 144/470 reads (31%) | called by muse, mutect2, varscan2
- C1QL3 | c.93C>G p.V31= | Silent (SNP) | VAF 57/363 reads (16%) | called by muse, mutect2, varscan2
- C22orf42 | c.240C>T p.D80= | Silent (SNP) | VAF 45/326 reads (14%) | catalogued as rs761214648, COSV66076324; called by muse, mutect2, varscan2
- C6orf163 | c.564G>T p.V188= | Silent (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- CCT6A | c.1155T>G p.T385= | Silent (SNP) | VAF 38/380 reads (10%) | called by muse, mutect2, varscan2
- CNTN2 | c.1245C>T p.L415= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1325980365, COSV59352594; called by muse, mutect2, varscan2
- COL10A1 | c.1614T>A p.P538= | Silent (SNP) | VAF 45/210 reads (21%) | called by muse, mutect2
- DDI1 | c.1053C>T p.I351= | Silent (SNP) | VAF 18/682 reads (3%) | catalogued as rs1226735014, COSV56368599, COSV56374872; called by muse, mutect2
- DOT1L | c.3084G>C p.L1028= | Silent (SNP) | VAF 36/132 reads (27%) | called by muse, mutect2, varscan2
- DYRK4 | c.870G>C p.L290= | Silent (SNP) | VAF 20/215 reads (9%) | called by muse, mutect2
- EML6 | c.4302C>G p.T1434= | Silent (SNP) | VAF 23/204 reads (11%) | called by muse, mutect2, varscan2
- GPSM1 | c.741C>T p.A247= | Silent (SNP) | VAF 33/269 reads (12%) | catalogued as rs375775955; called by muse, mutect2, varscan2
- GRIN3B | c.2769G>A p.R923= | Silent (SNP) | VAF 25/90 reads (28%) | called by muse, mutect2, varscan2
- HSPA6 | c.1326C>A p.I442= | Silent (SNP) | VAF 21/177 reads (12%) | called by muse, mutect2, varscan2
- IGHJ2 | c.9C>T p.Y3= | Silent (SNP) | VAF 18/258 reads (7%) | catalogued as rs370780867; called by muse, mutect2
- KCNB1 | c.270C>T p.G90= | Silent (SNP) | VAF 34/236 reads (14%) | catalogued as rs762279881, COSV65566177, COSV65566453; called by muse, mutect2, varscan2
- KLHDC3 | c.300G>T p.G100= | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- KLK4 | c.627G>T p.G209= | Silent (SNP) | VAF 81/513 reads (16%) | catalogued as rs1398816587; called by muse, mutect2, varscan2
- LHX8 | c.447C>A p.V149= | Silent (SNP) | VAF 70/421 reads (17%) | catalogued as COSV53956641, COSV99633835; called by muse, mutect2, varscan2
- LMAN1L | c.771A>G p.P257= | Silent (SNP) | VAF 100/362 reads (28%) | called by muse, mutect2, varscan2
- LRRTM1 | c.1263C>T p.N421= | Silent (SNP) | VAF 15/142 reads (11%) | catalogued as rs1470218165, COSV54441649; called by muse, mutect2, varscan2
- MAP3K13 | c.993T>C p.S331= | Silent (SNP) | VAF 21/142 reads (15%) | called by muse, mutect2, varscan2
- MIB1 | c.1083G>A p.A361= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as rs761958763, COSV55092588; called by mutect2, varscan2
- MMEL1 | c.88C>T p.L30= | Silent (SNP) | VAF 70/214 reads (33%) | called by muse, varscan2
- NAV3 | c.4656G>T p.V1552= | Silent (SNP) | VAF 91/382 reads (24%) | catalogued as COSV99893365; called by muse, mutect2, varscan2
- NOX5 | c.1641G>A p.S547= | Silent (SNP) | VAF 34/174 reads (20%) | catalogued as rs367755214, COSV52986656, COSV99533711; called by muse, mutect2
- OSTM1 | c.186C>T p.L62= | Silent (SNP) | VAF 42/242 reads (17%) | catalogued as rs1408094234; called by muse, mutect2, varscan2
- PARS2 | c.1053C>A p.A351= | Silent (SNP) | VAF 23/85 reads (27%) | called by muse, mutect2, varscan2
- PCDH15 | c.3345C>A p.V1115= | Silent (SNP) | VAF 25/188 reads (13%) | called by muse, mutect2, varscan2
- PCK1 | c.891C>T p.N297= | Silent (SNP) | VAF 24/203 reads (12%) | catalogued as COSV60129509; called by muse, mutect2, varscan2
- PLCB1 | c.2004C>A p.G668= | Silent (SNP) | VAF 45/351 reads (13%) | called by muse, mutect2, varscan2
- PRKN | c.747G>T p.L249= | Silent (SNP) | VAF 113/725 reads (16%) | catalogued as rs1170693935; called by muse, mutect2, varscan2
- RESF1 | c.3936A>G p.A1312= | Silent (SNP) | VAF 24/231 reads (10%) | called by muse, mutect2, varscan2
- RGSL1 | c.90C>A p.S30= | Silent (SNP) | VAF 30/285 reads (11%) | called by muse, mutect2, varscan2
- RNF150 | c.615C>T p.S205= | Silent (SNP) | VAF 62/470 reads (13%) | called by muse, mutect2, varscan2
- SCCPDH | c.279A>G p.T93= | Silent (SNP) | VAF 47/430 reads (11%) | called by muse, mutect2, varscan2
- SHROOM2 | c.1815C>T p.S605= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as rs189876719; called by muse, mutect2
- SLITRK1 | c.1809G>A p.G603= | Silent (SNP) | VAF 61/368 reads (17%) | catalogued as rs1250130733, COSV65674811; called by muse, mutect2, varscan2
- SLITRK1 | c.1530G>T p.P510= | Silent (SNP) | VAF 47/382 reads (12%) | catalogued as rs1301689793, COSV100999801; called by muse, mutect2, varscan2
- SMURF2 | c.2208A>G p.L736= | Silent (SNP) | VAF 33/306 reads (11%) | called by muse, mutect2, varscan2
- SOX13 | c.1674G>A p.L558= | Silent (SNP) | VAF 51/436 reads (12%) | called by muse, mutect2, varscan2
- TADA2A | c.1209C>T p.N403= | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as rs780540038; called by muse, mutect2
- TLR4 | c.1038C>A p.P346= (on ENST00000355622 / NM_138554.5; = p.P306= on NM_003266.4) | Silent (SNP) | VAF 24/149 reads (16%) | catalogued as rs199497705; called by muse, mutect2, varscan2
- TMPRSS5 | c.594T>C p.S198= | Silent (SNP) | VAF 51/217 reads (24%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.897C>T p.T299= | Silent (SNP) | VAF 64/880 reads (7%) | called by muse, mutect2
- UNC80 | c.414C>T p.G138= | Silent (SNP) | VAF 100/439 reads (23%) | called by muse, mutect2, varscan2
- ZFHX4 | c.8064G>A p.S2688= | Silent (SNP) | VAF 57/503 reads (11%) | catalogued as rs755724817, COSV51472767, COSV51500973; called by muse, mutect2, varscan2
- ZFR2 | c.714G>T p.A238= | Silent (SNP) | VAF 23/125 reads (18%) | called by muse, mutect2, varscan2
- ZNF423 | c.2892C>A p.A964= (on ENST00000563137 / NM_001379286.1; = p.A956= on NM_015069.4) | Silent (SNP) | VAF 73/209 reads (35%) | called by muse, mutect2, varscan2
- ZNF521 | c.3066C>T p.C1022= | Silent (SNP) | VAF 59/167 reads (35%) | catalogued as rs143100224; called by muse, mutect2, varscan2
- ARMCX4 | c.1039-3879C>A | Intron (SNP) | VAF 12/201 reads (6%) | called by muse, mutect2
- C5orf17 | n.371C>A | RNA (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- CDH11 | c.1895-573G>T | Intron (SNP) | VAF 66/188 reads (35%) | catalogued as rs749121210; called by muse, mutect2, varscan2
- CHN1 | c.712+2668G>A | Intron (SNP) | VAF 24/318 reads (8%) | called by muse, mutect2
- COL9A2 | c.364-36C>T | Intron (SNP) | VAF 30/298 reads (10%) | called by muse, mutect2
- CPED1 | c.540+3813A>T | Intron (SNP) | VAF 29/309 reads (9%) | called by muse, mutect2
- FAM205BP | n.86G>A | RNA (SNP) | VAF 20/303 reads (7%) | called by muse, mutect2
- GDAP1 | c.*1085G>T | 3'UTR (SNP) | VAF 31/237 reads (13%) | called by muse, mutect2, varscan2
- GPR35 | c.-524T>A | 5'UTR (SNP) | VAF 32/208 reads (15%) | called by muse, mutect2, varscan2
- KCNK1 | c.356-16617dup | Intron (INS) | VAF 58/308 reads (19%) | called by mutect2, pindel, varscan2
- MARK4 | c.1877+241G>A | Intron (SNP) | VAF 42/252 reads (17%) | catalogued as rs767049510, COSV53464930; called by muse, varscan2
- MIR222 | n.19T>G | RNA (SNP) | VAF 20/190 reads (11%) | called by muse, mutect2, varscan2
- MIRLET7BHG | n.309-3656G>T | Intron (SNP) | VAF 22/363 reads (6%) | called by muse, mutect2
- NUDT9P1 | n.523G>T | RNA (SNP) | VAF 82/542 reads (15%) | called by muse, mutect2, varscan2
- PPA2 | c.656-6669C>T | Intron (SNP) | VAF 51/351 reads (15%) | catalogued as rs575830146; called by muse, mutect2, varscan2
- RIMS2 | c.177-44412C>A | Intron (SNP) | VAF 198/552 reads (36%) | called by muse, mutect2, varscan2
- SLC17A2 | c.*132A>G | 3'UTR (SNP) | VAF 43/408 reads (11%) | called by muse, mutect2, varscan2
- SPTA1 | c.6788+9G>T | Intron (SNP) | VAF 34/387 reads (9%) | called by muse, mutect2
- ST14 | c.441-86C>T | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- UGT2B27P | n.106G>C | RNA (SNP) | VAF 58/424 reads (14%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1339C>A | 3'UTR (SNP) | VAF 33/160 reads (21%) | catalogued as rs374713962; called by muse, mutect2, varscan2
